Somatic mutation profile of tumor specimen TCGA-43-2581-01A (aliquot TCGA-43-2581-01A-01D-1522-08) from TCGA case TCGA-43-2581, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.8 years (17,447 days).
Specimen TCGA-43-2581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cee9bcdd-50fa-461e-b7e0-12e162d2bb87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-2581-11A (Solid Tissue Normal), aliquot TCGA-43-2581-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd0f834f-2c40-48eb-b495-9f7b4cac8fee

The open-access MAF lists 825 somatic variants for this specimen: 646 protein-altering or splice-affecting, 156 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 560, Silent 156, Nonsense Mutation 47, Frame Shift Del 14, Splice Site 10, Intron 10, Splice Region 9, RNA 6, Frame Shift Ins 3, 5'UTR 3, Translation Start Site 2, 3'UTR 2.

Variants (750 of 825; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99933534; called by muse, mutect2, varscan2
- ABCB10 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV100748099; called by muse, mutect2, varscan2
- ABCB5 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.615); catalogued as COSV99330081; called by muse, mutect2, varscan2
- ABCC8 | c.1402A>T p.I468F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV100217841, COSV56852322; called by muse, mutect2, varscan2
- ABRAXAS2 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100045218; called by muse, mutect2, varscan2
- AC100868.1 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV51841113, COSV99227187; called by muse, mutect2, varscan2
- ACAN | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1242151781, COSV100719434; called by muse, mutect2, varscan2
- ACER1 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100034160; called by muse, mutect2, varscan2
- ACKR1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100929700; called by muse, mutect2, varscan2
- ACSM2A | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV54584620, COSV99525817; called by muse, mutect2, varscan2
- ACTBL2 | c.898T>G p.L300V | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV101379437; called by muse, varscan2
- ACTL9 | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100185597, COSV61004846; called by muse, mutect2, varscan2
- ADAD1 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.437); catalogued as COSV99636426; called by muse, mutect2, varscan2
- ADAM15 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.762); catalogued as COSV99665451; called by muse, mutect2, varscan2
- ADAMTS1 | c.2274G>C p.Q758H | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53169802, COSV99536615; called by muse, mutect2, varscan2
- ADAMTS2 | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs144078893; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS5 | c.846G>T p.L282F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs762742485, COSV99538510; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2061G>T p.Q687H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101002108; called by muse, mutect2, varscan2
- ADARB1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100653560; called by muse, mutect2, varscan2
- ADARB1 | c.1988G>A p.R663H (on ENST00000360697 / NM_001346687.2; = p.R623H on NM_001112.4) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as rs775065806, COSV100654187; called by muse, mutect2, varscan2
- ADGRB3 | c.1718G>C p.R573T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101002058; called by muse, mutect2, varscan2
- ADGRF3 | c.2882C>G p.P961R (on ENST00000311519 / NM_001145168.1; = p.P762R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100274968, COSV100275534; called by muse, mutect2, varscan2
- ADH1A | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266024; called by muse, mutect2, varscan2
- ADH1B | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 57/302 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100520896; called by muse, mutect2, varscan2
- AFG1L | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780217981, COSV100934043; called by muse, mutect2, varscan2
- AGMO | c.63C>A p.Y21* | Nonsense Mutation (SNP) | VAF 46/242 reads (19%) | catalogued as COSV100694903; called by muse, mutect2, varscan2
- AIM2 | c.396+2T>C p.X132_splice | Splice Site (SNP) | VAF 42/215 reads (20%) | catalogued as COSV100931168; called by muse, mutect2, varscan2
- AMER1 | c.2796C>G p.D932E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100367174; called by muse, mutect2, varscan2
- ANKEF1 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV101001089; called by muse, mutect2, varscan2
- ANKRD13C | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99257904; called by muse, varscan2
- ANKRD24 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99518285; called by muse, mutect2, varscan2
- ANKRD30A | c.3505A>T p.K1169* (on ENST00000611781; = p.K1113* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 76/310 reads (25%) | catalogued as COSV100654599; called by muse, mutect2
- ANKRD30A | c.3507A>T p.K1169N (on ENST00000611781; = p.K1113N on NM_052997.2) | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1209644461, COSV100654558; called by muse, mutect2
- ANKRD45 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV100322732; called by muse, mutect2, varscan2
- ANKRD7 | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99501428; called by muse, mutect2, varscan2
- ANKS4B | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100290000; called by muse, mutect2, varscan2
- ANO5 | c.1373G>A p.W458* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100202345; called by muse, mutect2, varscan2
- ANXA4 | c.563G>T p.W188L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.558); catalogued as COSV101268850; called by muse, mutect2, varscan2
- AP2B1 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251825; called by muse, mutect2, varscan2
- APC | c.8381G>C p.S2794T | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV57389610, COSV99970895; called by muse, mutect2, varscan2
- APOA5 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV99911545; called by muse, mutect2, varscan2
- APOB | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV99268636; called by muse, mutect2, varscan2
- ARHGAP30 | c.3221A>T p.Q1074L (on ENST00000368013 / NM_001025598.2; = p.Q863L on NM_181720.3) | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.306); catalogued as COSV100920123, COSV100920560; called by muse, mutect2, varscan2
- ARHGEF18 | c.1238G>T p.R413M (on ENST00000359920 / NM_001130955.2; = p.R309M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100150131; called by muse, mutect2, varscan2
- ARID1B | c.3583G>T p.G1195C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99273097; called by muse, mutect2, varscan2
- ASAP2 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as COSV99857023; called by muse, mutect2, varscan2
- ASPRV1 | c.385T>A p.W129R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100208671; called by muse, mutect2, varscan2
- ASS1 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100752869; called by muse, mutect2, varscan2
- ASTN1 | c.1968C>A p.F656L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV99923454; called by muse, mutect2, varscan2
- ASTN2 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100531031; called by muse, mutect2
- ASXL3 | c.5737G>C p.V1913L | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99327030; called by muse, mutect2, varscan2
- ATAD2 | c.482G>T p.R161I | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99785493; called by muse, mutect2
- ATP10B | c.2100G>T p.E700D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV100515944; called by muse, mutect2, varscan2
- ATP10D | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV99906294; called by muse, mutect2, varscan2
- ATP2B1 | c.2620G>T p.A874S | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs570457928, COSV53803084, COSV99666296; called by muse, mutect2, varscan2
- AVPR1A | c.1076G>T p.C359F | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100146930; called by muse, mutect2, varscan2
- BANK1 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100537009, COSV100537050; called by muse, mutect2
- BEND3 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944616; called by muse, mutect2
- BOLL | c.600+2T>A p.X200_splice | Splice Site (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99987507; called by muse, mutect2, varscan2
- BRD8 | c.2835C>A p.N945K | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV99137858; called by muse, mutect2, varscan2
- BRWD1 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100314335; called by muse, mutect2, varscan2
- BTK | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.991); catalogued as CM952088, COSV58118475; called by muse, mutect2, varscan2
- C10orf90 | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52949332, COSV99505386; called by muse, mutect2, varscan2
- C9orf24 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99898169; called by muse, mutect2, varscan2
- CACNA1A | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803426; called by muse, mutect2, varscan2
- CACNA1E | c.6676C>A p.R2226S (on ENST00000367573 / NM_001205293.3; = p.R2183S on NM_000721.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV100705332, COSV100705796; called by muse, mutect2, varscan2
- CACNA1H | c.4560C>G p.D1520E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100673663; called by muse, mutect2, varscan2
- CADM3 | c.843G>T p.E281D (on ENST00000368125 / NM_001127173.3; = p.E315D on NM_021189.5) | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.101); catalogued as COSV100930441; called by muse, mutect2, varscan2
- CALCR | c.1211C>A p.A404E (on ENST00000649521 / NM_001164737.2; = p.A388E on NM_001742.4) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749628730, COSV100810913, COSV64009509; called by mutect2, varscan2
- CALU | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99975973; called by muse, mutect2, varscan2
- CASD1 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as rs780009738, COSV99803191; called by muse, mutect2, varscan2
- CCDC63 | c.1393C>A p.R465S | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs762320804, COSV57528395, COSV57531719; called by muse, mutect2, varscan2
- CCDC88C | c.3358G>T p.V1120L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101106359; called by muse, varscan2
- CCL24 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs989134700, COSV99768899; called by muse, mutect2, varscan2
- CCT8L2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV100743237; called by muse, mutect2, varscan2
- CD180 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as rs746380841, COSV99842454; called by muse, mutect2, varscan2
- CD6 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100533329; called by muse, mutect2, varscan2
- CDADC1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99212622; called by muse, mutect2, varscan2
- CDH10 | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100053468, COSV52593832, COSV52594063; called by muse, mutect2, varscan2
- CDH12 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV101203443, COSV101203477; called by muse, mutect2, varscan2
- CDK14 | c.635A>T p.Y212F (on ENST00000380050 / NM_001287135.2; = p.Y194F on NM_012395.3) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99727414; called by muse, mutect2, varscan2
- CDK5R2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as rs1233130991, COSV100226007; called by muse, mutect2, varscan2
- CDKL2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277241; called by muse, mutect2, varscan2
- CELSR2 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.872); catalogued as COSV99604964; called by muse, mutect2, varscan2
- CEP135 | c.1111-1G>A p.X371_splice | Splice Site (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99954969; called by muse, mutect2, varscan2
- CEP170 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100318060; called by muse, mutect2, varscan2
- CES5A | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866011, COSV99308157; called by muse, mutect2
- CFAP36 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs372141624; called by muse, mutect2, varscan2
- CFAP74 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.523); catalogued as COSV99574868; called by muse, mutect2, varscan2
- CGN | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642976; called by muse, mutect2, varscan2
- CGNL1 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849346; called by muse, mutect2, varscan2
- CHAMP1 | c.2144G>A p.C715Y | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100778893; called by muse, mutect2, varscan2
- CHD9 | c.6782A>T p.D2261V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99529890; called by muse, varscan2
- CHI3L2 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100869338; called by muse, mutect2, varscan2
- CHRNA4 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs752812151, COSV100937505; called by muse, mutect2, varscan2
- CLCN1 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100578663; called by muse, mutect2, varscan2
- CMYA5 | c.8578G>T p.D2860Y | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV101484451, COSV71409422; called by muse, mutect2, varscan2
- CNBD1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101575307; called by muse, mutect2, varscan2
- CNGA3 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs769433253, COSV55623924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNKSR2 | c.1933A>G p.K645E | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99670177; called by muse, mutect2, varscan2
- CNOT8 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99597299; called by muse, mutect2, varscan2
- CNTNAP3 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.934); catalogued as COSV99905822; called by muse, mutect2, varscan2
- COBL | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.666); catalogued as COSV99474539; called by muse, mutect2, varscan2
- COL22A1 | c.2858A>T p.E953V | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100280869, COSV100281249; called by muse, mutect2, varscan2
- COL24A1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 25/271 reads (9%) | catalogued as COSV100994178; called by muse, mutect2
- COL25A1 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1330565456, COSV101211719; called by muse, mutect2, varscan2
- COL27A1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1266183112, COSV100621398; called by muse, mutect2, varscan2
- COL4A1 | c.3589G>C p.A1197P | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV101011639; called by muse, mutect2, varscan2
- COL9A1 | c.2152G>T p.G718* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100295860, COSV57892938; called by muse, mutect2, varscan2
- COPG1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV100136032; called by muse, mutect2, varscan2
- CORIN | c.1766C>A p.S589* | Nonsense Mutation (SNP) | VAF 25/165 reads (15%) | catalogued as rs1176505390, COSV99904640; called by muse, mutect2, varscan2
- CPB1 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV99294598; called by muse, mutect2
- CPEB1 | c.1763G>T p.R588L (on ENST00000617958; = p.R523L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99918075; called by muse, mutect2, varscan2
- CPED1 | c.1065C>A p.C355* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV60006478; called by muse, mutect2
- CPQ | c.540C>G p.Y180* | Nonsense Mutation (SNP) | VAF 18/181 reads (10%) | catalogued as COSV99615497; called by muse, mutect2
- CRELD2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs370691392; called by muse, mutect2, varscan2
- CRHBP | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99169548; called by muse, mutect2, varscan2
- CSF1R | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99643404; called by muse, mutect2, varscan2
- CSMD1 | c.3607G>T p.D1203Y (on ENST00000520002; = p.D1202Y on NM_033225.6) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs749555971, COSV100154840, COSV59297299; called by muse, mutect2, varscan2
- CSTF2T | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV58657104, COSV58657270; called by muse, mutect2, varscan2
- CTAGE1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV101194725; called by muse, mutect2, varscan2
- CTCFL | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99713491; called by muse, mutect2, varscan2
- CTNNA2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV63568315; called by muse, mutect2, varscan2
- CTNNA3 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146777494; ClinVar: uncertain significance; called by muse, mutect2
- CUBN | c.6179G>T p.G2060V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100913721; called by muse, mutect2, varscan2
- CXCL2 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs775781780, COSV99933233; called by muse, mutect2, varscan2
- CXCL5 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs767718489, COSV99932964; called by muse, mutect2, varscan2
- CYP11A1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762145358, COSV99166293; called by muse, mutect2, varscan2
- CYP4X1 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.551); catalogued as COSV100903384; called by muse, mutect2
- CYYR1 | c.453C>G p.N151K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.394); catalogued as rs781224725, COSV100177711, COSV54832337; called by muse, mutect2, varscan2
- DCAF12L1 | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64421692, COSV64422635; called by muse, mutect2, varscan2
- DCAF12L1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100948482; called by muse, mutect2, varscan2
- DCSTAMP | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 60/222 reads (27%) | catalogued as COSV99887091; called by muse, mutect2, varscan2
- DDX10 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490062; called by muse, mutect2, varscan2
- DENND3 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV99371886; called by muse, mutect2, varscan2
- DENND4B | c.318G>T p.G106= | Splice Region (SNP) | VAF 41/117 reads (35%) | catalogued as COSV100339406; called by muse, mutect2, varscan2
- DGKI | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV99937829; called by muse, mutect2, varscan2
- DHRS3 | c.596T>C p.M199T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100879714; called by muse, mutect2, varscan2
- DMGDH | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV99669628; called by muse, mutect2, varscan2
- DNAAF2 | c.500C>A p.T167K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100024270; called by mutect2, varscan2
- DNAH17 | c.12907C>G p.R4303G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428580; called by muse, varscan2
- DPCD | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100924367; called by muse, mutect2, varscan2
- DRD2 | c.960C>A p.D320E | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100670261; called by muse, mutect2, varscan2
- DSG4 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV100356526; called by muse, mutect2, varscan2
- DTNA | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV52011516; called by muse, mutect2, varscan2
- DUSP26 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.06); catalogued as COSV99823608; called by muse, mutect2, varscan2
- DYNC2H1 | c.11265G>C p.M3755I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100520005; called by mutect2, varscan2
- EDC4 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100739359, COSV62765887; called by muse, mutect2, varscan2
- EFL1 | c.1402G>T p.G468W | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV99189160; called by muse, mutect2, varscan2
- EIPR1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV66132501; called by muse, mutect2, varscan2
- EPG5 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as COSV99958311; called by muse, mutect2, varscan2
- EPHA10 | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100140208; called by muse, mutect2, varscan2
- EPHA3 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758942025, COSV100349587; called by muse, varscan2
- EPPK1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101599983, COSV73261333; called by muse, mutect2
- ERBB4 | c.630G>T p.R210S | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV53550433; called by muse, mutect2, varscan2
- ERICH3 | c.4381A>T p.S1461C | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as COSV100446073; called by muse, mutect2, varscan2
- ERICH3 | c.2815G>C p.V939L | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100446074; called by muse, mutect2
- ESRRB | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV99835908; called by muse, mutect2, varscan2
- EZHIP | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100539960; called by muse, mutect2, varscan2
- FAM135B | c.3291G>T p.Q1097H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99428522; called by muse, mutect2, varscan2
- FANCB | c.2173A>T p.T725S | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV100146719; called by muse, mutect2, varscan2
- FAT3 | c.13501A>T p.S4501C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV99972239; called by muse, mutect2, varscan2
- FAT4 | c.5920G>C p.G1974R | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627684, COSV100630539; called by muse, mutect2, varscan2
- FAT4 | c.11449G>C p.G3817R | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627355, COSV100630540; called by muse, mutect2, varscan2
- FBN2 | c.3230G>T p.C1077F | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99331359; called by muse, mutect2, varscan2
- FBN2 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99331360; called by muse, mutect2
- FBXL14 | c.412A>T p.I138L | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.785); catalogued as COSV100201670; called by muse, mutect2, varscan2
- FEZF1 | c.150C>A p.H50Q | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100484576; called by muse, mutect2, varscan2
- FGF8 | c.282G>T p.M94I (on ENST00000344255 / NM_033164.4; = p.M76I on NM_006119.6) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV100199480; called by muse, mutect2, varscan2
- FGFR1 | c.2366C>G p.S789C (on ENST00000447712 / NM_023110.3; = p.S787C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100249539; called by muse, mutect2, varscan2
- FLG | c.10144C>T p.R3382C | Missense Mutation (SNP) | VAF 46/880 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs147066553, COSV64245007; called by muse, mutect2
- FLG2 | c.1391T>C p.L464S | Missense Mutation (SNP) | VAF 177/474 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101166300; called by muse, mutect2, varscan2
- FMO1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773457494, COSV100707996; called by muse, mutect2, varscan2
- FMO1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100707997; called by muse, mutect2, varscan2
- FOXJ2 | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as rs1565630465, COSV50817472; called by muse, mutect2, varscan2
- FOXK1 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196051; called by muse, mutect2, varscan2
- FRG1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV57005407, COSV99904141; called by muse, mutect2, varscan2
- FSIP2 | c.17020T>G p.Y5674D | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100556890; called by muse, mutect2, varscan2
- FSIP2 | c.20666C>A p.S6889Y | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100556891; called by muse, mutect2, varscan2
- FZD1 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757168229, COSV99842847; called by muse, mutect2, varscan2
- G6PC2 | c.15C>A p.H5Q | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as COSV99960970; called by muse, mutect2, varscan2
- G6PC3 | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52243540; called by muse, mutect2, varscan2
- GABPB1 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99590231; called by muse, mutect2, varscan2
- GABRR3 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV101512367; called by muse, mutect2, varscan2
- GALNT10 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99770093; called by muse, varscan2
- GAPVD1 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99783916; called by muse, mutect2, varscan2
- GATA5 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV99436152; called by muse, mutect2, varscan2
- GBP5 | c.626-2A>T p.X209_splice | Splice Site (SNP) | VAF 33/161 reads (20%) | catalogued as COSV100600191, COSV58593866; called by mutect2, varscan2
- GBP6 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969726, COSV65012144; called by muse, mutect2, varscan2
- GBP7 | c.862A>C p.T288P | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99643593; called by muse, mutect2, varscan2
- GFI1 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs1262460074, COSV99647680; called by muse, mutect2, varscan2
- GFRA1 | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100816297; called by mutect2, varscan2
- GJA8 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53788621, COSV99569809; called by muse, mutect2, varscan2
- GNAQ | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99682178; called by muse, mutect2, varscan2
- GNAT2 | c.352A>T p.T118S | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100655950; called by muse, mutect2, varscan2
- GPR12 | c.789C>A p.C263* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV101197933; called by muse, mutect2, varscan2
- GPR156 | c.1787C>G p.P596R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100251784, COSV59939007; called by muse, mutect2, varscan2
- GPR55 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV101235935; called by muse, mutect2, varscan2
- GRIA1 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV99602852; called by muse, varscan2
- GRIK2 | c.2636C>A p.P879Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV59759746; called by muse, mutect2, varscan2
- GRIN2B | c.2368G>T p.E790* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as rs759594946, COSV101663223; called by muse, mutect2, varscan2
- GRM1 | c.1134C>A p.C378* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99269634; called by muse, mutect2, varscan2
- GRM1 | c.1135C>G p.R379G | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51113674, COSV99269636; called by muse, mutect2, varscan2
- GRM7 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100739259; called by muse, mutect2, varscan2
- GRM8 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100286762; called by muse, mutect2, varscan2
- GSDMC | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52693098, COSV52693954; called by muse, mutect2, varscan2
- GUCY1A2 | c.326T>A p.L109H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99977498; called by muse, mutect2, varscan2
- HDGFL3 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100220972; called by muse, mutect2, varscan2
- HELLS | c.1931G>T p.R644M | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492484; called by muse, mutect2, varscan2
- HMCN1 | c.3125G>C p.G1042A | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV54895190, COSV99637427; called by muse, mutect2, varscan2
- HOXA3 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 52/239 reads (22%) | catalogued as COSV100415756, COSV57827995, COSV57828442; called by muse, mutect2, varscan2
- HTR1B | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100885521; called by muse, mutect2, varscan2
- HTT | c.5111A>G p.Y1704C | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs1433865496, COSV61863199; called by muse, mutect2, varscan2
- HYDIN | c.2352C>G p.I784M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV99865949; called by muse, mutect2, varscan2
- IARS2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV100228695; called by muse, mutect2
- IGFN1 | c.3108G>C p.R1036S (on ENST00000295591 / NM_001367841.1; = p.R3493S on NM_001164586.2) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV99813756; called by muse, mutect2, varscan2
- IGHG2 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as rs771278286; called by muse, varscan2
- IGHV3-72 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 32/220 reads (15%) | catalogued as COSV101455380; called by muse, mutect2, varscan2
- IGKV1-17 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 90/353 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1473601437; called by muse, mutect2, varscan2
- IGSF11 | c.319A>T p.I107F (on ENST00000393775 / NM_001015887.3; = p.I106F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100678041; called by muse, mutect2, varscan2
- IGSF21 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246604; called by muse, mutect2
- IL2RA | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99906984; called by muse, varscan2
- IL2RB | c.1643C>A p.T548N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99345187; called by muse, mutect2, varscan2
- IL2RB | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.311); catalogued as COSV99345191; called by muse, mutect2, varscan2
- ILDR2 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs760889412, COSV54831479; called by muse, mutect2, varscan2
- IMPDH1 | c.1019G>T p.R340L (on ENST00000470772 / NM_001142573.2; = p.R426L on NM_000883.4) | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100118839; called by muse, mutect2, varscan2
- IMPG2 | c.648G>T p.L216F | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99516696; called by muse, mutect2
- INPP4B | c.2361G>T p.K787N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.681); catalogued as COSV99527292; called by mutect2, varscan2
- INPPL1 | c.1811G>T p.W604L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996756; called by muse, mutect2
- INSR | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100253781, COSV100254048; called by muse, mutect2, varscan2
- INTS10 | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV101208757; called by muse, mutect2
- IQGAP1 | c.4058A>T p.K1353M | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99185448; called by muse, mutect2, varscan2
- IQUB | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | catalogued as COSV100227427; called by muse, mutect2, varscan2
- IRF4 | c.986T>A p.L329Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); catalogued as COSV66705995; called by muse, mutect2, varscan2
- IRF8 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV51900137; called by muse, mutect2, varscan2
- IRGQ | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100338279; called by muse, mutect2, varscan2
- ISL1 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV100045766; called by muse, mutect2, varscan2
- ISL2 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99320928; called by muse, mutect2, varscan2
- ITGA2 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1028073086, COSV99671839; called by muse, mutect2, varscan2
- ITGAD | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772879786, COSV101210622; called by muse, mutect2, varscan2
- ITGAD | c.3430G>C p.A1144P | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV54931522, COSV99791500; called by mutect2, varscan2
- ITGAX | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99192082; called by muse, mutect2, varscan2
- JCAD | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs778946679, COSV100948628; called by muse, mutect2, varscan2
- JPH3 | c.1389G>C p.K463N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV99414175; called by muse, mutect2, varscan2
- KCNAB2 | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV99379678; called by muse, varscan2
- KCNH6 | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121304; called by muse, varscan2
- KCNJ12 | c.845del p.G282Afs*27 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | catalogued as COSV100054133; called by mutect2, varscan2
- KCNN1 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV99716419; called by mutect2, varscan2
- KCNT2 | c.3045G>C p.M1015I | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.146); catalogued as COSV54092250, COSV99657417; called by muse, mutect2, varscan2
- KIAA0895 | c.817C>A p.P273T (on ENST00000297063 / NM_001100425.2; = p.P222T on NM_015314.3) | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as COSV99767320; called by muse, mutect2, varscan2
- KIAA1109 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV52665026; called by muse, varscan2
- KIAA1109 | c.3560C>T p.P1187L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV99192100; called by muse, varscan2
- KIAA1549L | c.801T>A p.S267R (on ENST00000321505; = p.S564R on NM_012194.3) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99684713; called by muse, mutect2, varscan2
- KIAA2026 | c.5107A>T p.S1703C | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV101199246; called by muse, mutect2
- KIF18B | c.2198A>T p.K733M (on ENST00000593135 / NM_001265577.2; = p.K745M on NM_001264573.2) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100192687; called by muse, mutect2, varscan2
- KIF21A | c.4787A>C p.H1596P (on ENST00000361418 / NM_001378440.1; = p.H1583P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV100735765; called by muse, mutect2
- KIF7 | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101068103; called by muse, varscan2
- KLHL28 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753342; called by muse, mutect2, varscan2
- KMO | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV100844733; called by muse, mutect2, varscan2
- KPRP | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1251068129, COSV100908838; called by muse, mutect2, varscan2
- KRTAP11-1 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100190874; called by muse, mutect2, varscan2
- KRTAP13-2 | c.162G>T p.R54S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101299670, COSV101299681, COSV67762116; called by muse, mutect2, varscan2
- LACRT | c.252G>A p.L84= | Splice Region (SNP) | VAF 8/176 reads (5%) | catalogued as COSV99143932; called by muse, mutect2
- LCE3D | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as rs749727744, COSV100909887; called by muse, mutect2, varscan2
- LDAH | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99426027; called by muse, mutect2, varscan2
- LHFPL3 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101309088; called by muse, mutect2, varscan2
- LHX8 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99634588; called by mutect2, varscan2
- LILRB5 | c.126del p.K43Sfs*3 | Frame Shift Del (DEL) | VAF 48/212 reads (23%) | catalogued as COSV100300577, COSV60261450; called by mutect2, varscan2
- LIMS2 | c.110A>T p.H37L (on ENST00000355119 / NM_001161403.3; = p.H61L on NM_017980.4) | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99760815; called by muse, mutect2, varscan2
- LIX1L | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100811080; called by muse, mutect2, varscan2
- LMO7 | c.4527G>T p.Q1509H (on ENST00000357063; = p.Q1190H on NM_005358.5) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV100413988, COSV58541968; called by muse, mutect2, varscan2
- LPA | c.3723C>A p.N1241K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV100308306; called by muse, mutect2, varscan2
- LPAR3 | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101004891; called by muse, mutect2, varscan2
- LPXN | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101223171; called by muse, mutect2, varscan2
- LRP1B | c.13227G>T p.E4409D | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV101262140, COSV67262890; called by muse, mutect2, varscan2
- LRP1B | c.4018C>A p.L1340M | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV67218133; called by muse, varscan2
- LRRC32 | c.1766G>T p.R589L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.274); catalogued as rs565593386, COSV99477408; called by muse, mutect2, varscan2
- LRRC56 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as COSV99531035; called by muse, mutect2
- LRRC66 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58633823, COSV58636144; called by muse, mutect2, varscan2
- LRRIQ1 | c.4914G>T p.Q1638H | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV67831561; called by muse, varscan2
- LRTM2 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99766760; called by muse, mutect2, varscan2
- LTB | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV101438069; called by muse, mutect2
- LTBP1 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 93/533 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100618063; called by muse, mutect2, varscan2
- LUZP2 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV100421710, COSV61219643; called by muse, mutect2, varscan2
- LY6H | c.250T>C p.F84L | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV100713959, COSV61370443; called by muse, mutect2
- MAGI1 | c.4198G>T p.D1400Y | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs370430462; called by muse, mutect2, varscan2
- MAP4K4 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV100156132; called by muse, mutect2, varscan2
- MBL2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906436; called by muse, varscan2
- MCM8 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1356448202, COSV99177633; called by muse, mutect2, varscan2
- MDC1 | c.3074A>T p.K1025M | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.187); catalogued as COSV100903146; called by muse, mutect2, varscan2
- MED26 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs540302307, COSV99660247; called by muse, mutect2, varscan2
- MED26 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.335); catalogued as COSV99660250; called by mutect2, varscan2
- MEGF10 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV99175863; called by muse, mutect2, varscan2
- MEOX2 | c.548T>A p.V183D | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV100012623; called by muse, mutect2, varscan2
- MKRN3 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100091784; called by muse, mutect2
- MMD2 | c.560T>A p.L187H (on ENST00000404774 / NM_001100600.2; = p.L163H on NM_198403.4) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101287203; called by muse, mutect2, varscan2
- MMRN1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as rs1374890443, COSV99307922; called by muse, mutect2, varscan2
- MMRN1 | c.2003C>G p.P668R | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99307923; called by muse, mutect2, varscan2
- MOGAT3 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV99777382; called by muse, varscan2
- MORC4 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99717730; called by muse, varscan2
- MORC4 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.81); catalogued as COSV99717732; called by muse, varscan2
- MOXD1 | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100382037; called by muse, mutect2, varscan2
- MPDZ | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV100065229; called by muse, mutect2, varscan2
- MRC1 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 83/440 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509749, COSV58890064; called by muse, mutect2, varscan2
- MRGPRD | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100483105; called by muse, mutect2, varscan2
- MS4A5 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.27); catalogued as COSV100281160; called by muse, mutect2, varscan2
- MTA1 | c.950G>C p.W317S | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100495531; called by muse, varscan2
- MTA1 | c.951G>T p.W317C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV100495533; called by muse, varscan2
- MTR | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855603; called by muse, mutect2, varscan2
- MTTP | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55504335; called by muse, varscan2
- MUC16 | c.41769G>T p.E13923D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.953); catalogued as COSV66692902; called by muse, mutect2, varscan2
- MUC16 | c.5012C>A p.S1671Y | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV101201640; called by muse, varscan2
- MUC16 | c.1805A>T p.Q602L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV101202117; called by muse, mutect2, varscan2
- MUC2 | c.2368G>T p.G790C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs766773398; called by muse, mutect2, varscan2
- MXRA5 | c.7926G>T p.Q2642H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as COSV99479758; called by muse, varscan2
- MXRA5 | c.6490C>A p.L2164I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99479761; called by muse, mutect2, varscan2
- MYCBP2 | c.9707G>T p.S3236I (on ENST00000357337; = p.S3274I on NM_015057.5) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100632371; called by muse, mutect2, varscan2
- MYCBPAP | c.2815C>A p.L939I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs749299098, COSV99277542; called by muse, mutect2, varscan2
- MYEF2 | c.1682C>G p.S561* | Nonsense Mutation (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99982274; called by muse, mutect2
- MYH3 | c.2378G>T p.C793F | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV99879067; called by muse, mutect2, varscan2
- MYH7 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 40/200 reads (20%) | catalogued as COSV100806826; called by muse, mutect2, varscan2
- MYL10 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99781239; called by mutect2, varscan2
- MYLK | c.4695C>A p.Y1565* | Nonsense Mutation (SNP) | VAF 40/207 reads (19%) | catalogued as COSV100659795; called by muse, mutect2, varscan2
- MYLK2 | c.1224+2T>A p.X408_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | catalogued as COSV101044981; called by muse, mutect2, varscan2
- NCAN | c.3342G>T p.K1114N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV53055254, COSV99388576; called by muse, mutect2
- NCAN | c.3343G>T p.D1115Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99388578; called by muse, mutect2
- NCOR1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1214744460, COSV99250464, COSV99252677; called by muse, mutect2, varscan2
- NCSTN | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV99617051; called by muse, mutect2, varscan2
- NES | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs750670255, COSV63962642; called by muse, mutect2, varscan2
- NEURL4 | c.2951G>T p.G984V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.5); catalogued as COSV100223374; called by muse, mutect2, varscan2
- NIBAN3 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.471); catalogued as COSV99962830; called by muse, mutect2, varscan2
- NLRC3 | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV100073603; called by muse, mutect2, varscan2
- NLRC5 | c.3076C>T p.Q1026* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs759791431, COSV52658373; called by muse, mutect2, varscan2
- NLRP11 | c.1749C>A p.Y583* | Nonsense Mutation (SNP) | VAF 46/226 reads (20%) | catalogued as COSV100789830; called by muse, mutect2, varscan2
- NLRP13 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs893731940, COSV100738638; called by muse, mutect2, varscan2
- NLRP13 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100738315; called by muse, mutect2
- NLRP5 | c.2933C>A p.P978H | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101173963, COSV66765677; called by mutect2, varscan2
- NPY1R | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.757); catalogued as rs375717997, COSV99649120; called by muse, mutect2, varscan2
- NPY5R | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV100642979; called by muse, varscan2
- NRXN1 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV68002975; called by muse, mutect2, varscan2
- NRXN2 | c.3406G>C p.G1136R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99636329; called by muse, mutect2, varscan2
- NSD3 | c.1771A>T p.T591S | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100389014; called by muse, mutect2, varscan2
- NSDHL | c.702G>T p.L234F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV100938701; called by muse, varscan2
- NSDHL | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV100938703; called by muse, mutect2, varscan2
- NTNG1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV53969555, COSV99640074; called by muse, mutect2, varscan2
- NTNG2 | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100647832; called by muse, mutect2, varscan2
- NTRK3 | c.1012A>T p.N338Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100448348; called by muse, mutect2, varscan2
- NTSR1 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100980734; called by muse, varscan2
- NUDT7 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99216255; called by muse, mutect2, varscan2
- NUDT7 | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV99216257; called by muse, mutect2, varscan2
- NUP98 | c.3636G>T p.M1212I (on ENST00000359171 / NM_001365126.1; = p.M1195I on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100263686; called by muse, mutect2
- OBI1 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs767115602, COSV56144943, COSV99932679; called by muse, mutect2, varscan2
- OLFM3 | c.238G>T p.D80Y (on ENST00000338858 / NM_001288821.1; = p.D60Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100130248; called by muse, mutect2, varscan2
- OLFM4 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs373925038, COSV54581281; called by muse, mutect2, varscan2
- OMD | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV100979100; called by muse, mutect2, varscan2
- OR10A6 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564378, COSV59166205; called by muse, mutect2, varscan2
- OR10A7 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100406644; called by muse, mutect2, varscan2
- OR10C1 | c.306G>T p.M102I (on ENST00000622521; = p.M100I on NM_013941.3) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101010897; called by muse, mutect2, varscan2
- OR13C8 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100623044, COSV99080309; called by muse, mutect2, varscan2
- OR13C9 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1447535469, COSV99403596; called by muse, mutect2, varscan2
- OR1L1 | c.113G>C p.C38S | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1182247314, COSV100542294; called by muse, mutect2, varscan2
- OR2L13 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63547965, COSV63552086, COSV63559650; called by muse, mutect2, varscan2
- OR2M4 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV100141587, COSV60708076, COSV60708583; called by muse, mutect2, varscan2
- OR2M4 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs746091746, COSV100141589; called by muse, mutect2, varscan2
- OR2T2 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs750175037, COSV100737818, COSV61617748; called by muse, varscan2
- OR2T2 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100737731, COSV100737820; called by muse, varscan2
- OR2T6 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100861666, COSV63215679; called by muse, varscan2
- OR2T6 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100861669; called by muse, varscan2
- OR4A5 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs760137860, COSV100157359; called by mutect2, varscan2
- OR4D5 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 68/326 reads (21%) | catalogued as COSV100190238; called by muse, mutect2, varscan2
- OR4K13 | c.760T>A p.C254S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV100237934; called by muse, mutect2, varscan2
- OR4L1 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs747772078, COSV100235951; called by muse, mutect2, varscan2
- OR4P4 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745688826, COSV100111896; called by muse, varscan2
- OR52W1 | c.935C>A p.T312N | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1369217932, COSV100258768; called by muse, mutect2, varscan2
- OR5AS1 | c.658T>G p.C220G | Missense Mutation (SNP) | VAF 59/520 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as COSV100546427; called by muse, varscan2
- OR6K2 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs778393764, COSV100656924, COSV62744127; called by muse, mutect2, varscan2
- OR7A10 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.018); catalogued as COSV99932539; called by muse, mutect2, varscan2
- OR7D4 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100432707, COSV100432899; called by muse, mutect2, varscan2
- OR9A2 | c.833C>G p.T278S | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV100628304; called by muse, mutect2, varscan2
- OSCP1 | c.282G>T p.Q94H (on ENST00000356637 / NM_001330493.1; = p.Q84H on NM_145047.5) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV99347664; called by muse, varscan2
- OTOF | c.5480G>T p.R1827L (on ENST00000272371 / NM_194248.3; = p.R1060L on NM_004802.4) | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV99719299; called by muse, mutect2, varscan2
- OTX2 | c.488C>T p.P163L (on ENST00000408990 / NM_172337.3; = p.P171L on NM_021728.4) | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV100258121, COSV59766937; called by muse, mutect2, varscan2
- OVCH1 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100549343; called by mutect2, varscan2
- PACRGL | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.487); catalogued as COSV99764413; called by muse, mutect2, varscan2
- PADI2 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100971118; called by muse, mutect2, varscan2
- PAGE3 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100892005, COSV100892026; called by muse, mutect2, varscan2
- PAPPA2 | c.2672G>T p.R891L | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100867259, COSV62772532; called by muse, mutect2, varscan2
- PARN | c.1416G>C p.Q472H | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs766730789, COSV100420743; called by muse, mutect2, varscan2
- PASD1 | c.1844G>T p.R615I | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100949719; called by muse, varscan2
- PAX4 | c.584C>G p.P195R | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490386; called by muse, mutect2, varscan2
- PAX8 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV99640210; called by muse, mutect2
- PCDH11X | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs777825266, COSV53476341, COSV53478524; called by muse, mutect2, varscan2
- PCDHA2 | c.2310G>T p.M770I | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV100974186; called by muse, mutect2
- PCDHA3 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 52/283 reads (18%) | catalogued as COSV100793820, COSV100793834; called by muse, mutect2, varscan2
- PCDHA5 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs782278628, COSV100972620; called by muse, mutect2, varscan2
- PCDHA8 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100971115; called by muse, mutect2
- PCDHB12 | c.1798del p.A600Pfs*31 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as COSV53395557; called by mutect2, pindel, varscan2
- PCDHB14 | c.2116C>A p.L706I | Missense Mutation (SNP) | VAF 60/379 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.111); catalogued as COSV99506382; called by muse, mutect2, varscan2
- PCDHGA1 | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100966163; called by muse, mutect2, varscan2
- PCDHGA6 | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV99549030; called by muse, mutect2
- PCDHGA8 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV53984142, COSV99549034; called by muse, mutect2, varscan2
- PCDHGB2 | c.1889G>C p.R630P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99549025; called by muse, mutect2, varscan2
- PCLO | c.6462A>T p.Q2154H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV100439218; called by muse, varscan2
- PCYOX1L | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV99199319; called by muse, mutect2
- PDE10A | c.659G>C p.W220S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.333); catalogued as COSV100606092; called by muse, mutect2, varscan2
- PDGFRA | c.1448C>G p.T483S | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV99957951; called by muse, mutect2, varscan2
- PDILT | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as rs1200321723, COSV100199884; called by muse, mutect2, varscan2
- PDXDC1 | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs532163268, COSV100363524; called by muse, mutect2
- PELP1 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99343512; called by muse, mutect2, varscan2
- PIGA | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100363572; called by muse, mutect2, varscan2
- PIK3CG | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100783274, COSV63247881; called by muse, mutect2, varscan2
- PIKFYVE | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV100011619; called by muse, mutect2, varscan2
- PLEKHA5 | c.2779A>G p.I927V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV100164905; called by muse, mutect2, varscan2
- PLXNA2 | c.3068G>C p.S1023T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.324); catalogued as COSV100886146; called by muse, mutect2, varscan2
- PLXNA4 | c.2834C>A p.S945Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100327877, COSV58113459; called by muse, mutect2
- PNLIPRP3 | c.277A>T p.I93L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100982658; called by muse, mutect2, varscan2
- PNN | c.1703A>C p.N568T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV99397452; called by muse, mutect2
- POLR1A | c.2375A>T p.Y792F | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.176); catalogued as rs775617280, COSV99808609; called by muse, mutect2, varscan2
- POT1 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV62928517; called by muse, mutect2, varscan2
- PPA2 | c.939G>T p.S313= (on ENST00000341695 / NM_176869.3; = p.S284= on NM_006903.4) | Splice Region (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100500851, COSV58996044; called by muse, mutect2, varscan2
- PPHLN1 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV99872507; called by muse, varscan2
- PPP6R3 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99677800; called by muse, mutect2, varscan2
- PRDM16 | c.1952del p.G651Afs*33 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | catalogued as COSV54609443; called by mutect2, varscan2
- PRDM2 | c.5110A>G p.K1704E | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs1199131703, COSV99342944; called by muse, mutect2, varscan2
- PRICKLE1 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100566717; called by muse, mutect2, varscan2
- PRKCG | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV99669662; called by muse, mutect2, varscan2
- PRMT7 | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV59832934; called by muse, mutect2, varscan2
- PRPF19 | c.1133A>T p.D378V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99920823; called by muse, mutect2, varscan2
- PRPF3 | c.2018C>A p.A673E | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100255183; called by muse, mutect2, varscan2
- PRR16 | c.391C>T p.P131S (on ENST00000407149 / NM_001300783.2; = p.P108S on NM_016644.2) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV101088418, COSV65398398; called by muse, mutect2, varscan2
- PRR30 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99574884; called by muse, mutect2, varscan2
- PSG4 | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 62/548 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV99738014; called by muse, varscan2
- PSMA8 | c.102G>T p.A34= | Splice Region (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100379201, COSV57601028; called by muse, mutect2
- PTBP1 | c.970G>T p.G324C (on ENST00000349038 / NM_031991.4; = p.G350C on NM_002819.5) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100609225; called by muse, mutect2, varscan2
- PTPRD | c.4949G>T p.R1650L | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100647633; called by muse, mutect2, varscan2
- PTPRD | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100647636, COSV61925280; called by muse, mutect2, varscan2
- PTPRJ | c.1874-1G>T p.X625_splice | Splice Site (SNP) | VAF 30/197 reads (15%) | catalogued as COSV101395808; called by muse, mutect2, varscan2
- PTPRK | c.3001G>T p.D1001Y (on ENST00000368215 / NM_001291984.2; = p.D1002Y on NM_002844.4) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100951720; called by muse, mutect2, varscan2
- PXDNL | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687032; called by muse, mutect2, varscan2
- PXDNL | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687033, COSV62487345; called by muse, mutect2, varscan2
- PXK | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100244515; called by muse, mutect2, varscan2
- RABL3 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99846683; called by muse, mutect2, varscan2
- RAG1 | c.3047G>T p.G1016V | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100201225; called by muse, mutect2, varscan2
- RALGDS | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100924573; called by muse, mutect2, varscan2
- RALYL | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101569561, COSV72819296; called by muse, mutect2, varscan2
- RANBP6 | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424492; called by muse, varscan2
- RBBP4 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV100995809; called by muse, mutect2, varscan2
- RBM28 | c.290G>C p.C97S | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99775979; called by muse, mutect2
- REG3G | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV55450372, COSV55452555; called by mutect2, varscan2
- RELN | c.9311A>G p.H3104R | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as COSV100635128; called by muse, mutect2
- REXO4 | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV100905784; called by muse, mutect2, varscan2
- RGS22 | c.3629A>T p.Y1210F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100693949; called by muse, mutect2, varscan2
- RGS6 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100667210; called by mutect2, varscan2
- RNF20 | c.2846G>T p.R949L | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101206591, COSV66661379; called by mutect2, varscan2
- ROBO2 | c.3391A>T p.T1131S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV100170562; called by muse, mutect2, varscan2
- RUNX1T1 | c.892C>A p.Q298K (on ENST00000265814 / NM_001198628.1; = p.Q271K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV56153323, COSV99755718; called by muse, mutect2, varscan2
- RYR1 | c.2054G>T p.W685L | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617282; called by muse, mutect2, varscan2
- RYR1 | c.3770C>A p.S1257Y | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100617283; called by muse, mutect2, varscan2
- RYR2 | c.10246G>T p.E3416* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100773271; called by muse, mutect2, varscan2
- RYR2 | c.12400G>T p.G4134C | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63683791; called by muse, mutect2, varscan2
- SAMD7 | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.479); catalogued as COSV100157125; called by muse, mutect2, varscan2
- SCN5A | c.6027C>A p.D2009E (on ENST00000333535 / NM_198056.3; = p.D2008E on NM_000335.5) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100351178; called by muse, mutect2, varscan2
- SEC16A | c.2209A>T p.N737Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99260476; called by muse, mutect2, varscan2
- SECISBP2 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV100368920; called by muse, varscan2
- SELP | c.2264C>A p.S755* | Nonsense Mutation (SNP) | VAF 57/161 reads (35%) | catalogued as COSV99741353; called by muse, mutect2, varscan2
- SEMA3A | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV99548260; called by muse, mutect2
- SEMA3D | c.1558A>G p.I520V | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99407559; called by muse, mutect2, varscan2
- SEMA5A | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101228770; called by muse, mutect2, varscan2
- SERPINA9 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV100098953; called by muse, mutect2, varscan2
- SERPINB12 | c.1036C>G p.H346D | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99501955; called by muse, mutect2, varscan2
- SI | c.2278G>T p.A760S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100017520; called by muse, mutect2, varscan2
- SIDT1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334933; called by muse, mutect2, varscan2
- SIGLEC12 | c.576G>T p.K192N (on ENST00000291707 / NM_053003.4; = p.K74N on NM_033329.2) | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99389669; called by muse, mutect2, varscan2
- SLC12A5 | c.217G>T p.E73* (on ENST00000454036 / NM_001134771.2; = p.E50* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 82/442 reads (19%) | catalogued as COSV54794133, COSV99717057; called by muse, mutect2, varscan2
- SLC14A2 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV54907449, COSV99676309; called by muse, mutect2, varscan2
- SLC18A3 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100341079, COSV60334292; called by muse, mutect2, varscan2
- SLC1A5 | c.1390G>T p.D464Y | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314840; called by muse, mutect2
- SLC22A1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs1045389610, COSV100267105; called by muse, mutect2, varscan2
- SLC23A3 | c.1798G>C p.E600Q (on ENST00000409878 / NM_001144889.2; = p.E483Q on NM_144712.5) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs753216257, COSV99841456; called by muse, mutect2, varscan2
- SLC25A47 | c.73-1G>T p.X25_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100836610; called by muse, mutect2, varscan2
- SLC2A8 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV100972725; called by mutect2, varscan2
- SLC43A3 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100725281; called by muse, mutect2, varscan2
- SLC4A3 | c.1955A>T p.Y652F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as COSV99813380; called by muse, mutect2
- SLC4A3 | c.2735A>C p.K912T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56096508, COSV99813384; called by muse, mutect2
- SLC5A12 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 38/244 reads (16%) | catalogued as COSV101237782; called by muse, varscan2
- SLC5A12 | c.798del p.C266* | Frame Shift Del (DEL) | VAF 38/259 reads (15%) | catalogued as COSV54825104; called by mutect2, pindel, varscan2
- SLC7A13 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs776603092, COSV99879308; called by muse, mutect2, varscan2
- SLC8A3 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776416; called by muse, mutect2, varscan2
- SLC8A3 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776418; called by muse, mutect2, varscan2
- SLCO1C1 | c.1768G>T p.G590C | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779608364, COSV99860177; called by muse, mutect2, varscan2
- SLCO2A1 | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100189486; called by muse, mutect2, varscan2
- SLIT1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.306); catalogued as COSV99822783; called by muse, mutect2, varscan2
- SLITRK1 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 36/179 reads (20%) | catalogued as COSV101000102; called by muse, mutect2, varscan2
- SLITRK3 | c.1808G>C p.R603P | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99579206, COSV99580353; called by muse, mutect2, varscan2
- SMO | c.1571C>A p.A524D | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV50824992, COSV99977205; called by muse, mutect2, varscan2
- SMPD3 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99546154; called by muse, varscan2
- SMYD1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 73/407 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101352546; called by muse, mutect2, varscan2
- SNX16 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100629724; called by muse, mutect2
- SNX29 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100030478, COSV60061855; called by muse, mutect2
- SPHK1 | c.346C>A p.L116M (on ENST00000392496 / NM_001355139.2; = p.L130M on NM_021972.4) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100039624; called by muse, mutect2, varscan2
- SPINK6 | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100347222; called by muse, mutect2
- SPTB | c.1513A>G p.N505D | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV101072473; called by muse, mutect2, varscan2
- SRRM2 | c.7693G>T p.G2565C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV99241783; called by muse, mutect2, varscan2
- ST6GAL2 | c.1339A>T p.M447L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | PolyPhen benign (0.001); catalogued as COSV100699705; called by muse, mutect2
- STARD8 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs373340258, COSV99366238; called by muse, mutect2, varscan2
- STC2 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 66/609 reads (11%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.919); catalogued as COSV99438798; called by muse, mutect2, varscan2
- STIL | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54552708, COSV99681435; called by muse, mutect2, varscan2
- STIP1 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1365151666, COSV100534999; called by muse, mutect2, varscan2
- STPG2 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99762080; called by muse, mutect2, varscan2
- SULT1C4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV99731905; called by muse, mutect2, varscan2
- TAS2R60 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100223693; called by muse, mutect2, varscan2
- TAZ | c.369A>T p.R123= | Splice Region (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99186413; called by muse, mutect2, varscan2
- TBC1D28 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100561102; called by muse, mutect2
- TBK1 | c.1669A>T p.N557Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100538477; called by muse, mutect2, varscan2
- TBX19 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100892433; called by muse, mutect2, varscan2
- TCAF1 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584746; called by muse, mutect2, varscan2
- TCL1A | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV101268500; called by muse, mutect2, varscan2
- TENM2 | c.2585G>T p.C862F (on ENST00000518659 / NM_001122679.2; = p.C630F on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101319494; called by muse, mutect2, varscan2
- TF | c.1019C>G p.T340S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV99396526; called by muse, mutect2, varscan2
- TFAP2C | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.239); catalogued as rs748899621, COSV99571858; called by muse, mutect2, varscan2
- THOP1 | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100310840; called by muse, varscan2
- THSD7B | c.1358G>C p.R453T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99759346; called by muse, mutect2
- TKTL2 | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99761410; called by muse, mutect2, varscan2
- TMEM108 | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV58873083; called by muse, mutect2, varscan2
- TMEM161B | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV99680890; called by muse, mutect2
- TMEM178A | c.893G>T p.*298Lext*43 | Nonstop Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV99932102; called by muse, mutect2, varscan2
- TMEM200A | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99760254; called by muse, mutect2, varscan2
- TMPRSS11F | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100678878; called by muse, mutect2, varscan2
- TNNT3 | c.399G>T p.A133= (on ENST00000397301 / NM_001367846.1; = p.A122= on NM_006757.4) | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99548873; called by mutect2, varscan2
- TNR | c.3406C>A p.Q1136K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.763); catalogued as COSV99692092; called by muse, mutect2
- TNR | c.2292G>T p.L764F | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99692097; called by muse, mutect2, varscan2
- TOP2B | c.1850A>T p.D617V (on ENST00000264331 / NM_001330700.2; = p.D612V on NM_001068.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99980477; called by muse, mutect2, varscan2
- TOX2 | c.995C>T p.P332L (on ENST00000358131 / NM_001098798.2; = p.P308L on NM_032883.3) | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100364855; called by muse, mutect2, varscan2
- TOX2 | c.1346G>T p.C449F (on ENST00000358131 / NM_001098798.2; = p.C425F on NM_032883.3) | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100364405; called by muse, mutect2, varscan2
- TRA2A | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV99767925; called by muse, mutect2, varscan2
- TRERF1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs770725567, COSV100551923; called by muse, mutect2, varscan2
- TRIM23 | c.1290G>T p.M430I | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.29); catalogued as COSV99140333; called by muse, mutect2
- TRIM27 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV101019515; called by muse, mutect2, varscan2
- TRIM58 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV100825156; called by muse, mutect2, varscan2
- TRPA1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085491; called by muse, mutect2, varscan2
- TRPA1 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100085495; called by muse, mutect2, varscan2
- TRPC1 | c.948T>A p.Y316* (on ENST00000476941 / NM_001251845.2; = p.Y282* on NM_003304.4) | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99859453; called by muse, varscan2
- TRPV4 | c.2465G>T p.W822L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV99028263; called by muse, mutect2, varscan2
- TRPV5 | c.1870G>T p.G624W | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521155; called by muse, mutect2, varscan2
- TRUB2 | c.240G>T p.L80= | Splice Region (SNP) | VAF 27/179 reads (15%) | catalogued as COSV55958499; called by muse, mutect2, varscan2
- TSC2 | c.2802G>T p.R934S | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99555646; called by muse, mutect2, varscan2
- TSPAN18 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV100419013; called by muse, mutect2, varscan2
- TSPEAR | c.818C>G p.P273R | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.072); catalogued as COSV100555875; called by muse, mutect2
- TTN | c.26768A>G p.K8923R (on ENST00000591111; = p.K7996R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/165 reads (9%) | PolyPhen probably damaging (0.994); catalogued as COSV100634616; called by muse, mutect2
- TTN | c.7927G>T p.V2643F (on ENST00000591111; = p.V2597F on NM_003319.4) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | PolyPhen probably damaging (0.998); catalogued as rs886042338, COSV100589579; ClinVar: uncertain significance; called by muse, mutect2
- TTPA | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99478661; called by muse, mutect2, varscan2
- TUBB8 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100226224; called by muse, mutect2, varscan2
- TYRP1 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV101141494; called by muse, mutect2, varscan2
- UGT2B11 | c.669G>T p.W223C | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV101485313; called by muse, mutect2, varscan2
- UHRF2 | c.1393-1G>T p.X465_splice | Splice Site (SNP) | VAF 20/79 reads (25%) | catalogued as rs1445124374, COSV99437332; called by mutect2, varscan2
- UNC13C | c.816C>A p.H272Q | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99524073; called by muse, mutect2, varscan2
- UNC5A | c.1941C>G p.D647E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV99459604; called by muse, mutect2, varscan2
- UNC5A | c.2363G>T p.S788I | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99459606; called by muse, mutect2, varscan2
- UROS | c.466A>T p.K156* | Nonsense Mutation (SNP) | VAF 58/287 reads (20%) | catalogued as COSV100909085; called by muse, mutect2, varscan2
- USP17L2 | c.867C>A p.N289K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.055); catalogued as COSV100414802; called by muse, mutect2, varscan2
- USP29 | c.2024C>T p.T675I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99518846; called by muse, mutect2, varscan2
- USP34 | c.2233A>T p.I745F | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV101277293; called by muse, mutect2, varscan2
- USP6 | c.2901G>T p.W967C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.962); catalogued as COSV100005148; called by muse, mutect2, varscan2
- VCAN | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 19/136 reads (14%) | catalogued as COSV99427713; called by muse, mutect2, varscan2
- VPS11 | c.1133C>T p.T378I (on ENST00000620429; = p.T922I on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV99598256; called by muse, mutect2, varscan2
- VPS13B | c.5147C>T p.T1716I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs966152558, COSV100663956; called by muse, mutect2, varscan2
- VPS54 | c.1011G>T p.R337= | Splice Region (SNP) | VAF 14/71 reads (20%) | catalogued as rs375030990; called by muse, mutect2, varscan2
- VPS8 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV99804385; called by muse, mutect2, varscan2
- VWA8 | c.2845G>T p.E949* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as COSV99865453; called by muse, mutect2, varscan2
- WDR64 | c.2616A>T p.Q872H | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as COSV100844132; called by muse, mutect2, varscan2
- WDR7 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99590677; called by muse, mutect2, varscan2
- WDR93 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756537285, COSV99175887; called by mutect2, varscan2
- WFIKKN2 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100260166; called by muse, mutect2, varscan2
- WHAMM | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV54496118; called by muse, mutect2, varscan2
- WWC2 | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV101331123; called by muse, mutect2, varscan2
- XIRP2 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV99748736; called by muse, mutect2, varscan2
- XIRP2 | c.9385C>A p.R3129S (on ENST00000628543; = p.R3304S on NM_152381.6) | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99748747; called by muse, mutect2, varscan2
- YARS1 | c.942A>T p.E314D | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.884); catalogued as COSV100993528; called by muse, mutect2, varscan2
- YIPF7 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274413; called by muse, mutect2, varscan2
- ZBBX | c.1565C>A p.S522Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV56785804, COSV56796180; called by muse, mutect2
- ZBTB16 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100252303; called by muse, mutect2, varscan2
- ZBTB40 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 17/190 reads (9%) | catalogued as COSV100989142; called by muse, mutect2
- ZFHX4 | c.4851C>A p.H1617Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99268888; called by muse, mutect2, varscan2
- ZFHX4 | c.5711C>A p.A1904D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99268894; called by muse, mutect2, varscan2
- ZFYVE1 | c.1518G>T p.G506= | Splice Region (SNP) | VAF 46/190 reads (24%) | catalogued as COSV100607203; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV100048632; called by muse, varscan2
- ZMYM4 | c.1927G>T p.V643L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV100111269; called by muse, mutect2, varscan2
- ZNF160 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV100762515; called by muse, mutect2, varscan2
- ZNF19 | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99867777; called by muse, varscan2
- ZNF235 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs756560416, COSV52158623, COSV99349796; called by muse, mutect2, varscan2
- ZNF25 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 23/171 reads (13%) | catalogued as COSV100224826; called by muse, mutect2, varscan2
- ZNF256 | c.66C>A p.Y22* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | catalogued as COSV99991113; called by muse, mutect2, varscan2
- ZNF317 | c.1576G>C p.G526R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99927404; called by muse, mutect2, varscan2
- ZNF329 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100798842; called by muse, mutect2, varscan2
- ZNF385A | c.422-2A>T p.X141_splice (on ENST00000338010 / NM_001130967.3; = p.X121_splice on NM_015481.3) | Splice Site (SNP) | VAF 44/143 reads (31%) | catalogued as COSV100567032; called by muse, mutect2, varscan2
- ZNF385B | c.1424G>T p.R475L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375494558, COSV100416545; called by muse, mutect2, varscan2
- ZNF385D | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as COSV99875039; called by muse, mutect2, varscan2
- ZNF407 | c.5557A>T p.S1853C | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100227476; called by muse, mutect2, varscan2
- ZNF423 | c.2967C>A p.H989Q (on ENST00000563137 / NM_001379286.1; = p.H981Q on NM_015069.4) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99284232; called by muse, varscan2
- ZNF423 | c.1085G>T p.S362I (on ENST00000563137 / NM_001379286.1; = p.S354I on NM_015069.4) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99284236; called by muse, mutect2, varscan2
- ZNF423 | c.884C>A p.P295Q (on ENST00000563137 / NM_001379286.1; = p.P287Q on NM_015069.4) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); catalogued as COSV52184195, COSV52201454; called by muse, mutect2, varscan2
- ZNF43 | c.1236G>C p.K412N | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs879124559, COSV100731995; called by muse, mutect2, varscan2
- ZNF479 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100483165; called by muse, mutect2, varscan2
- ZNF480 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as COSV57995388; called by muse, mutect2, varscan2
- ZNF483 | c.2218T>A p.F740I | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV100493161; called by muse, mutect2
- ZNF486 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV100631572; called by muse, mutect2, varscan2
- ZNF497 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV99568778; called by muse, mutect2
- ZNF555 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100514800; called by muse, mutect2, varscan2
- ZNF566 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV101091653; called by muse, mutect2, varscan2
- ZNF585A | c.1981C>T p.P661S (on ENST00000292841 / NM_001288800.2; = p.P606S on NM_152655.3) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99493714; called by muse, mutect2, varscan2
- ZNF616 | c.1757A>T p.Y586F | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100348512, COSV100348680; called by muse, mutect2, varscan2
- ZNF626 | c.146A>T p.K49M | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV99391883; called by muse, mutect2, varscan2
- ZNF711 | c.1574G>T p.R525I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99341730; called by muse, mutect2, varscan2
- ZNF74 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100677597; called by muse, mutect2, varscan2
- ZNF8 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV99544622; called by muse, mutect2, varscan2
- ZNF816 | c.1196G>T p.C399F | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554744; called by muse, mutect2, varscan2
- ZNF830 | c.510A>T p.E170D | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs1229632912, COSV100031091; called by muse, mutect2, varscan2
- ZNF831 | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100926261, COSV100926319; called by muse, mutect2, varscan2
- ZNF85 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100060205; called by muse, mutect2, varscan2
- ZZEF1 | c.1762A>G p.M588V | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67556245; called by muse, mutect2, varscan2
- C3 | c.786del p.K263Rfs*40 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | called by mutect2, pindel, varscan2
- COL11A1 | c.1921_1922del p.P641Kfs*6 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- DKK2 | c.560del p.S187* | Frame Shift Del (DEL) | VAF 37/197 reads (19%) | called by mutect2, pindel, varscan2
- DUOX1 | c.2643-2del p.X881_splice | Splice Site (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel
- FCGBP | c.5656G>T p.G1886W | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FGF4 | c.484del p.L162Ffs*20 | Frame Shift Del (DEL) | VAF 27/228 reads (12%) | called by mutect2, pindel, varscan2
- GAK | c.2498del p.G833Dfs*112 | Frame Shift Del (DEL) | VAF 52/262 reads (20%) | called by mutect2, varscan2
- GPR37 | c.561del p.K188Nfs*58 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2
- IGHM | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.146); called by muse, mutect2
- KLHL10 | c.994C>A p.H332N | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LSMEM1 | c.192dup p.V65Cfs*30 | Frame Shift Ins (INS) | VAF 24/209 reads (11%) | called by mutect2, pindel, varscan2
- MDH1 | c.515del p.G172Vfs*2 | Frame Shift Del (DEL) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- NYX | c.1268C>A p.P423Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR51B5 | c.23dup p.H8Qfs*41 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.1537C>G p.L513V | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBP3 | c.795C>A p.D265E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SERPINA9 | c.882del p.W294* | Frame Shift Del (DEL) | VAF 31/162 reads (19%) | called by mutect2, varscan2
- TDRD6 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX35 | c.668dup p.P224Afs*8 | Frame Shift Ins (INS) | VAF 5/27 reads (19%) | called by pindel, varscan2
- TRBC2 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TRGV5 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZFHX4 | c.1814del p.G605Efs*28 | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- ZNF98 | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- ABCA4 | c.1353C>A p.I451= | Silent (SNP) | VAF 60/283 reads (21%) | catalogued as COSV100933332; called by muse, mutect2, varscan2
- ABCA8 | c.3177A>T p.T1059= | Silent (SNP) | VAF 116/263 reads (44%) | catalogued as COSV99287164; called by muse, mutect2, varscan2
- ACTBL2 | c.897G>T p.V299= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV101379439; called by muse, varscan2
- ADAM8 | c.1548G>A p.Q516= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs755556120, COSV101291764, COSV69864804; called by muse, mutect2, varscan2
- ADCY6 | c.1023G>T p.L341= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV100327006, COSV57168103; called by muse, mutect2, varscan2
- ADCY9 | c.3369G>A p.A1123= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as rs778234726, COSV53571497; called by muse, mutect2, varscan2
- ADRA2B | c.1338C>A p.T446= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1198721475, COSV101337399; called by muse, mutect2
- AGT | c.63C>A p.I21= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV100794507; called by muse, mutect2, varscan2
- ANK2 | c.6735A>G p.E2245= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100004705; called by muse, mutect2
- AP5S1 | c.222G>T p.R74= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99853338; called by muse, mutect2, varscan2
- APOB | c.12669G>A p.E4223= | Silent (SNP) | VAF 44/221 reads (20%) | catalogued as COSV99268634; called by muse, mutect2, varscan2
- ARAP3 | c.111G>A p.R37= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV99500423; called by muse, mutect2, varscan2
- ATF6 | c.762A>C p.P254= | Silent (SNP) | VAF 43/253 reads (17%) | catalogued as COSV100909561; called by muse, mutect2, varscan2
- ATP4A | c.570G>A p.Q190= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99383191; called by muse, mutect2, varscan2
- C4orf51 | c.348T>C p.F116= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as COSV101440047; called by muse, mutect2, varscan2
- CARMIL2 | c.1807C>A p.R603= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100576404; called by muse, mutect2
- CCDC186 | c.976C>A p.R326= | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as COSV100991149; called by muse, mutect2, varscan2
- CD180 | c.39G>T p.L13= | Silent (SNP) | VAF 22/201 reads (11%) | catalogued as COSV99842456; called by muse, mutect2, varscan2
- CDO1 | c.456G>T p.V152= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99164846; called by muse, mutect2, varscan2
- CELF1 | c.1125C>T p.P375= (on ENST00000358597 / NM_001376422.1; = p.P371= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 30/178 reads (17%) | catalogued as COSV100137285; called by muse, mutect2, varscan2
- CEP128 | c.660G>T p.V220= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99383826; called by muse, mutect2
- CHRM2 | c.405G>T p.R135= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV100280681; called by muse, mutect2, varscan2
- CORO2B | c.108C>A p.I36= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99963848; called by muse, mutect2, varscan2
- CPB1 | c.1248G>C p.L416= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV99294596; called by muse, mutect2
- CREB3L3 | c.243C>T p.S81= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV50184496; called by muse, mutect2, varscan2
- CSGALNACT1 | c.543G>T p.V181= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100175791; called by muse, varscan2
- CTRC | c.15T>A p.T5= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV101036488; called by muse, mutect2, varscan2
- CUL5 | c.306A>G p.T102= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs754673122, COSV101263768; called by muse, mutect2, varscan2
- DHX16 | c.589C>T p.L197= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV100906185; called by muse, mutect2, varscan2
- DNAH7 | c.2280A>G p.Q760= | Silent (SNP) | VAF 76/322 reads (24%) | catalogued as COSV100418120; called by muse, mutect2, varscan2
- DNAI4 | c.1521C>T p.H507= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100925363; called by muse, mutect2, varscan2
- DNAJB8 | c.321G>T p.L107= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100048535; called by muse, mutect2, varscan2
- ELL | c.1398C>T p.P466= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs775807945, COSV99443850; called by muse, mutect2, varscan2
- FAM234A | c.201A>G p.S67= | Silent (SNP) | VAF 33/534 reads (6%) | catalogued as COSV100056701; called by muse, mutect2
- FAM83B | c.2736T>C p.P912= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as COSV100175182; called by muse, mutect2, varscan2
- FER1L6 | c.1791C>A p.S597= | Silent (SNP) | VAF 72/407 reads (18%) | catalogued as COSV101206240; called by muse, mutect2, varscan2
- FHOD3 | c.450G>C p.L150= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV57184297; called by muse, mutect2, varscan2
- FIGN | c.1533G>T p.A511= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs767299659, COSV100293067, COSV60772231; called by muse, mutect2, varscan2
- FNIP2 | c.1998C>T p.P666= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100033395; called by muse, mutect2, varscan2
- GAL3ST3 | c.231G>T p.T77= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100361024, COSV61749866; called by muse, mutect2, varscan2
- GAL3ST4 | c.1078C>A p.R360= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs570514466, COSV100385672, COSV57586143; called by muse, mutect2, varscan2
- GBP7 | c.861C>A p.V287= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV99643595; called by muse, mutect2, varscan2
- GFI1B | c.402C>A p.S134= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100254561; called by muse, mutect2, varscan2
- GPR61 | c.270C>T p.A90= | Silent (SNP) | VAF 110/336 reads (33%) | catalogued as rs772632780, COSV101344423; called by muse, mutect2, varscan2
- GRID1 | c.1797G>T p.P599= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100027064; called by muse, mutect2, varscan2
- GRIN3A | c.1068G>T p.L356= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs1236064909, COSV100701930; called by muse, mutect2, varscan2
- GRM5 | c.1779C>A p.A593= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100554959; called by muse, mutect2, varscan2
- HELZ | c.3648C>T p.Y1216= | Silent (SNP) | VAF 58/174 reads (33%) | catalogued as rs1229103623, COSV100699120; called by muse, mutect2, varscan2
- HTN1 | c.121C>A p.R41= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as rs371461805, COSV55895274, COSV99887607; called by muse, mutect2, varscan2
- HTT | c.6285G>T p.P2095= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100751373; called by muse, mutect2, varscan2
- IFNL2 | c.414G>T p.R138= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as COSV100122140; called by muse, mutect2, varscan2
- IGDCC4 | c.2481C>T p.G827= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1368090341, COSV100732646; called by muse, mutect2, varscan2
- IGHA2 | c.213C>A p.T71= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- IGHV3-13 | c.253C>A p.R85= | Silent (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- IMPDH1 | c.1020G>T p.R340= (on ENST00000470772 / NM_001142573.2; = p.R426= on NM_000883.4) | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100118838; called by muse, mutect2, varscan2
- ITPR1 | c.1065G>T p.L355= (on ENST00000354582; = p.L340= on NM_002222.7) | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as COSV100233630; called by muse, mutect2, varscan2
- KIAA1109 | c.3558T>A p.I1186= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV52662352, COSV99192069; called by muse, varscan2
- KIDINS220 | c.3231G>C p.L1077= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV99876614; called by muse, mutect2
- KLHDC8B | c.564G>T p.P188= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100234354; called by muse, mutect2, varscan2
- KLHL14 | c.1656C>A p.L552= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV100839331; called by muse, mutect2, varscan2
- LPA | c.3297C>A p.T1099= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs770611055, COSV100308309; called by muse, mutect2, varscan2
- LRP1B | c.1830A>T p.G610= | Silent (SNP) | VAF 52/244 reads (21%) | catalogued as COSV101262145; called by muse, varscan2
- LRRC27 | c.594G>T p.P198= | Silent (SNP) | VAF 46/252 reads (18%) | catalogued as rs774713378, COSV100690006, COSV59812391; called by muse, mutect2, varscan2
- LRRC32 | c.1950C>T p.C650= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs755948676, COSV99477407; called by muse, mutect2, varscan2
- LTB | c.594G>A p.G198= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101438070; called by muse, mutect2
- MARCO | c.777G>T p.G259= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100503916; called by muse, mutect2, varscan2
- MFSD13A | c.1029G>T p.L343= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV99488111; called by muse, mutect2, varscan2
- MGAM | c.789G>T p.V263= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV101516577; called by muse, mutect2
- MMP26 | c.174G>T p.L58= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100332288; called by muse, mutect2, varscan2
- MRPS36 | c.195G>C p.L65= | Silent (SNP) | VAF 53/212 reads (25%) | catalogued as COSV99841137; called by muse, mutect2, varscan2
- MS4A3 | c.381C>A p.A127= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV53936008, COSV99615081; called by muse, mutect2, varscan2
- MXRA5 | c.6489C>A p.T2163= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99479764; called by muse, mutect2, varscan2
- MYO1H | c.2652G>T p.P884= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100184106; called by muse, mutect2, varscan2
- MYO9B | c.4122A>T p.A1374= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV101262023; called by muse, mutect2, varscan2
- NCR3 | c.357A>C p.T119= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV99279232; called by muse, varscan2
- NEUROG2 | c.390G>T p.A130= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs773597723, COSV100511974; called by muse, mutect2, varscan2
- NFATC2IP | c.633G>A p.T211= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs755353194, COSV57909679, COSV57910436; called by muse, mutect2, varscan2
- NKX2-2 | c.24G>C p.T8= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV101010642, COSV65819216, COSV65820047; called by muse, mutect2, varscan2
- NLRP11 | c.1575G>C p.S525= | Silent (SNP) | VAF 54/331 reads (16%) | catalogued as COSV100789831; called by muse, mutect2, varscan2
- NRXN1 | c.399G>T p.V133= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV101277109; called by muse, mutect2, varscan2
- NWD1 | c.2439G>T p.L813= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100343920; called by muse, mutect2, varscan2
- OR10H2 | c.703C>A p.R235= | Silent (SNP) | VAF 49/227 reads (22%) | catalogued as COSV100008907; called by muse, mutect2, varscan2
- OR11H4 | c.204C>A p.P68= | Silent (SNP) | VAF 47/267 reads (18%) | catalogued as COSV100197649, COSV59560585; called by muse, mutect2, varscan2
- OR2T5 | c.177C>T p.L59= | Silent (SNP) | VAF 47/407 reads (12%) | catalogued as rs1240557470, COSV100822223; called by muse, mutect2, varscan2
- OR2W3 | c.756T>C p.Y252= | Silent (SNP) | VAF 98/289 reads (34%) | catalogued as rs1180053252, COSV100831885; called by muse, mutect2, varscan2
- OR4D1 | c.453G>T p.G151= | Silent (SNP) | VAF 48/237 reads (20%) | catalogued as COSV99274362; called by muse, mutect2, varscan2
- OR51T1 | c.396G>T p.L132= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- OR52K1 | c.774C>A p.V258= | Silent (SNP) | VAF 49/362 reads (14%) | catalogued as COSV100297758; called by muse, mutect2, varscan2
- OR52R1 | c.471G>T p.L157= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as COSV100617815; called by muse, mutect2, varscan2
- PCDHA7 | c.1791T>A p.V597= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV100971952; called by muse, mutect2
- PCDHB13 | c.1479C>T p.P493= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV99507989; called by muse, mutect2
- PCDHB4 | c.1155A>T p.P385= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV52020763; called by muse, mutect2, varscan2
- PCDHGA6 | c.1236G>T p.R412= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as COSV54025241, COSV54051204; called by muse, mutect2, varscan2
- PCDHGB2 | c.1695C>A p.P565= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99528381, COSV99549024; called by muse, mutect2, varscan2
- PGK2 | c.525C>A p.S175= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV100505748; called by muse, mutect2, varscan2
- PIAS3 | c.1083G>A p.K361= | Silent (SNP) | VAF 51/271 reads (19%) | catalogued as COSV100566889; called by muse, mutect2, varscan2
- PKP1 | c.585C>A p.A195= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99825819; called by muse, mutect2, varscan2
- PLPP7 | c.315C>A p.S105= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as COSV100952610; called by muse, varscan2
- POC5 | c.1485T>C p.D495= (on ENST00000428202 / NM_001099271.2; = p.D470= on NM_152408.2) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100994416; called by muse, mutect2, varscan2
- POFUT1 | c.663G>T p.T221= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV101003226; called by muse, mutect2, varscan2
- PPP3R2 | c.285G>T p.A95= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as COSV100701928, COSV62450522; called by muse, mutect2, varscan2
- PPP6R3 | c.2196A>T p.T732= (on ENST00000393800 / NM_001352375.2; = p.T652= on NM_018312.5) | Silent (SNP) | VAF 33/189 reads (17%) | catalogued as COSV55733075; called by muse, mutect2, varscan2
- PRAM1 | c.180G>T p.P60= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV99725927; called by muse, varscan2
- PRAMEF7 | c.1236T>A p.P412= | Silent (SNP) | VAF 25/311 reads (8%) | catalogued as rs1175729668; called by muse, mutect2
75 further variants in this file (0 protein-altering or splice-affecting, 52 silent, 23 other) are not listed here.
